Somatic mutation profile of tumor specimen 0DZ4NY from CCDI case PBCTRA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Other ill-defined sites; Age at diagnosis: 4.9 years (1,787 days).
Specimen 0DZ4NY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e55ccde2-1059-4f91-80b5-a1b2d825759e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DZ4MD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47751882-aa0b-46f2-a000-a95fae85e5a6

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C12orf56 | c.1163C>T p.P388L (on ENST00000543942 / NM_001170633.2; = p.P228L on NM_001099676.3) | Missense Mutation (SNP) | VAF 204/910 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs773391869; called by muse, mutect2, varscan2
- EIF3A | c.4064C>A p.S1355* | Nonsense Mutation (SNP) | VAF 291/1008 reads (29%) | catalogued as rs757963072; called by muse, mutect2, varscan2
- JAG1 | c.1415G>A p.R472H | Missense Mutation (SNP) | VAF 224/1008 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.018); catalogued as rs574349599; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF2B | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 155/457 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.877); catalogued as COSV52127569; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1850C>T p.P617L | Missense Mutation (SNP) | VAF 191/832 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1231037885, COSV50508033; called by muse, mutect2, varscan2
- FAM214A | c.1132G>T p.A378S | Missense Mutation (SNP) | VAF 34/1116 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- LINGO1 | c.823C>A p.L275M | Missense Mutation (SNP) | VAF 165/699 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PTBP3 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 174/641 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- APOA5 | c.526C>T p.L176= | Silent (SNP) | VAF 28/680 reads (4%) | called by muse, mutect2
- BRAP | c.555C>T p.N185= | Silent (SNP) | VAF 243/1085 reads (22%) | catalogued as rs778991696; called by muse, mutect2, varscan2
- LSM12 | c.138C>T p.S46= | Silent (SNP) | VAF 185/727 reads (25%) | called by muse, mutect2, varscan2
- CLDN16 | c.-162T>C | 5'UTR (SNP) | VAF 300/918 reads (33%) | called by muse, varscan2
